Somatic mutation profile of tumor specimen C3N-00552-02 (aliquot CPT0068100006) from CPTAC case C3N-00552, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 49.7 years (18,163 days).
Specimen C3N-00552-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5a9feed-065b-4162-b66a-89fbe3712a7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00552-71 (Blood Derived Normal), aliquot CPT0068210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/896d4ac3-94e8-4fd8-90c2-f7b177db9d72

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Frame Shift Del 4, Intron 2, 5'UTR 2, Frame Shift Ins 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 71/322 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.1488G>C p.R496S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.08); catalogued as rs759078059; called by muse, mutect2, varscan2
- COL19A1 | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs933117138; called by muse, mutect2, varscan2
- CWC25 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374088221; called by muse, mutect2, varscan2
- GOLGA4 | c.2336T>C p.V779A | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.074); catalogued as rs777969002; called by muse, mutect2, varscan2
- GPR162 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs782232955; called by muse, mutect2, varscan2
- HDAC9 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV67774967; called by muse, mutect2, varscan2
- INTS4 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs777210322; called by muse, mutect2, varscan2
- MYH9 | c.1565C>G p.P522R | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53386810; called by muse, mutect2, varscan2
- NCKAP5 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as rs961990100; called by muse, mutect2
- OR1Q1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs1457572702, COSV52917191; called by muse, varscan2
- PDCD10 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 77/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs868732450, COSV67102093, COSV67103181; called by muse, mutect2, varscan2
- SGSM1 | c.2663A>G p.N888S (on ENST00000400359 / NM_001039948.4; = p.N827S on NM_133454.3) | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs767665554; called by muse, mutect2
- SP6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567960467; called by muse, mutect2
- TNS3 | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs1213894548, COSV100236191; called by muse, mutect2, varscan2
- CACNG7 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.229); called by muse, mutect2
- CDT1 | c.1049A>G p.Q350R | Missense Mutation (SNP) | VAF 73/459 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FNBP4 | c.2717_2718insT p.P907Tfs*20 | Frame Shift Ins (INS) | VAF 26/199 reads (13%) | called by pindel, varscan2
- HSD17B3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- INTS9 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- LRRC8B | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAN2B2 | c.1039T>A p.F347I | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MTTP | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P2RY4 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ROCK2 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- SETD2 | c.3435del p.F1145Lfs*9 | Frame Shift Del (DEL) | VAF 31/205 reads (15%) | called by mutect2, pindel, varscan2
- SETD2 | c.1503_1506del p.Y501* | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by pindel, varscan2
- SLC35G5 | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMAD4 | c.1591_1601del p.R531Afs*42 | Frame Shift Del (DEL) | VAF 45/279 reads (16%) | called by mutect2, pindel
- SYNJ2 | c.1392G>T p.M464I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOGARAM1 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- TRIM51GP | c.1024del p.Y342Ifs*29 | Frame Shift Del (DEL) | VAF 86/450 reads (19%) | called by mutect2, pindel, varscan2
- UBE4A | c.2246A>T p.Y749F (on ENST00000252108 / NM_001204077.2; = p.Y756F on NM_004788.4) | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- XAGE3 | c.120_123dup p.E42Nfs*2 | Frame Shift Ins (INS) | VAF 21/155 reads (14%) | called by mutect2, pindel, varscan2
- IKZF3 | c.1443G>A p.E481= | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as rs1185794391; called by muse, mutect2, varscan2
- KCNK13 | c.1011G>A p.T337= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as rs764305711, COSV56410221; called by muse, mutect2, varscan2
- MRPS35 | c.9C>T p.A3= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- MTR | c.1227A>T p.G409= | Silent (SNP) | VAF 94/485 reads (19%) | called by muse, mutect2, varscan2
- NT5C2 | c.1116T>A p.I372= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- RALGAPB | c.1683C>T p.A561= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, varscan2
- SLC29A4 | c.1059C>T p.I353= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs1220988973; called by muse, mutect2, varscan2
- SPATA31D1 | c.132C>T p.Y44= | Silent (SNP) | VAF 56/302 reads (19%) | catalogued as rs1397482654, COSV100782606, COSV61193148; called by muse, mutect2, varscan2
- TBX18 | c.393C>T p.T131= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs1314718599; called by muse, mutect2, varscan2
- GLUD1 | c.-44C>G | 5'UTR (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- IFT43 | c.54+299A>C | Intron (SNP) | VAF 40/293 reads (14%) | called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46112710 ins CACGGAG | 5'Flank (INS) | VAF 33/195 reads (17%) | called by mutect2, varscan2
- PHGDH | c.356+1484C>T | Intron (SNP) | VAF 58/444 reads (13%) | catalogued as rs587599714; called by muse, mutect2
- ZNF738 | c.-58G>A | 5'UTR (SNP) | VAF 46/277 reads (17%) | called by muse, mutect2, varscan2
